Surgical pathology report (de-identified scan), TCGA case TCGA-HT-7694, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Case Western - St Joes, specimen TCGA-HT-7694-01A (Primary Tumor).

Tumor

Normal:

Slide:

Microscopic Description:

Sections demonstrate a glial neoplasm that diffusely infiltrates both gray and white matter. The tumor cells consistently have round, mildly enlarged nuclei and most have perinuclear halos. Atypia is mild to moderate. Scattered mitotic figures are seen with up to 6 mitoses seen in 10 high power fields. Neither microvascular proliferation nor necrosis are identified.

Addendum Discussion:

Numerous MIB-1 reactive cells are present. In most proliferative areas an estimated >25% of cells are positive, indicative of a highly proliferative neoplasm.

Diagnosis:

Right frontal tumor

Anaplastic oligodendroglioma (WHO grade III)

MIB-1 Labeling Index = >25 % (Estimated)

Source: NCI Genomic Data Commons file 13d881eb-14b7-471c-b117-4cfa7b78c219 (TCGA-HT-7694.09CB8FC6-43E0-484F-9897-B2DF70D0A16E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).